Somatic mutation profile of tumor specimen TARGET-10-PAREJZ-09A (aliquot TARGET-10-PAREJZ-09A-01D) from TARGET case TARGET-10-PAREJZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,901 days).
Specimen TARGET-10-PAREJZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36861e9f-38c5-413f-89b3-4f263993f944.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREJZ-10A (Blood Derived Normal), aliquot TARGET-10-PAREJZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70972b3e-ef99-4e18-bff4-effcd088fcda

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 4, Frame Shift Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 22/36 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DGKB | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs780682758, COSV51765107, COSV99339050; called by muse, mutect2, varscan2
- LILRB5 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as rs746812552, COSV60258251; called by muse, mutect2, varscan2
- NFKB2 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs1404051917; called by muse, mutect2, varscan2
- TPO | c.2537G>A p.R846Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.419); catalogued as rs141598673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPC4 | c.1097T>G p.F366C | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59017447; called by muse, mutect2, varscan2
- CCDC27 | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DCLK3 | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC41 | c.851del p.L284Wfs*18 | Frame Shift Del (DEL) | VAF 32/73 reads (44%) | called by mutect2, pindel, varscan2
- TTN | c.37921C>G p.L12641V (on ENST00000591111; = p.L5217V on NM_003319.4) | Missense Mutation (SNP) | VAF 42/106 reads (40%) | PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ZNF729 | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAJB2 | c.819C>T p.P273= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as rs766688134; called by muse, mutect2, varscan2
- ETHE1 | c.360C>A p.I120= | Silent (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- GLYATL2 | c.72C>T p.S24= | Silent (SNP) | VAF 80/146 reads (55%) | catalogued as rs775634096, COSV54850930; called by muse, mutect2, varscan2
- SLC5A4 | c.1368A>G p.T456= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as rs929576115; called by muse, mutect2, varscan2
- TDRD6 | c.1941C>T p.D647= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs757247390, COSV60177394; called by muse, mutect2, varscan2
- CACNB3 | c.291+90T>C | Intron (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- CASTOR1 | c.185-251C>A | Intron (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- GRIA2 | c.-24G>T | 5'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- SPICE1 | c.-1+327G>C | Intron (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- TTYH1 | c.*108T>C | 3'UTR (SNP) | VAF 31/73 reads (42%) | catalogued as rs373712429; called by muse, mutect2, varscan2
- ZMAT4 | c.349+11G>A | Intron (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
